Somatic mutation profile of tumor specimen TCGA-XF-AAN0-01A (aliquot TCGA-XF-AAN0-01A-11D-A42E-08) from TCGA case TCGA-XF-AAN0, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 68.1 years (24,877 days).
Specimen TCGA-XF-AAN0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0cb7dbd-ed78-4f8d-980c-0a3a323bdfda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-AAN0-10A (Blood Derived Normal), aliquot TCGA-XF-AAN0-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96fe06fc-13e3-4528-a346-6cd25b1eeb84

The open-access MAF lists 452 somatic variants for this specimen: 341 protein-altering or splice-affecting, 99 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 295, Silent 99, Nonsense Mutation 30, Intron 6, Splice Region 5, Nonstop Mutation 4, Splice Site 3, 5'Flank 3, Frame Shift Del 3, 3'UTR 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 59/97 reads (61%) | hotspot (GDC flag); catalogued as rs587783047, CM980317, COSV55728388, COSV55734769, COSV55741582; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 55/216 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MYH9 | c.4270G>A p.D1424N | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs80338831, CM002373, CM010348, CM014588, COSV53390646; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 22/46 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB10 | c.1278G>A p.M426I | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.69); PolyPhen benign (0.086); catalogued as rs1484911964, COSV60621110, COSV60622695; called by muse, mutect2, varscan2
- ACACB | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 69/141 reads (49%) | SIFT tolerated (0.65); PolyPhen benign (0.031); catalogued as COSV58141287; called by muse, mutect2, varscan2
- ACTL9 | c.290T>C p.F97S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV61006658; called by muse, mutect2, varscan2
- ADAMTS9 | c.4472G>A p.R1491K | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV55777396, COSV99898529; called by muse, mutect2, varscan2
- ADAR | c.2693C>T p.S898F | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52711774, COSV52718619; called by muse, mutect2, varscan2
- ADRA1D | c.1570G>A p.G524R | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); catalogued as COSV65240590, COSV65241577; called by muse, mutect2, varscan2
- AFG1L | c.106C>G p.L36V | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV64557094; called by muse, mutect2, varscan2
- AHCYL1 | c.900C>T p.G300= | Splice Region (SNP) | VAF 39/134 reads (29%) | catalogued as COSV63209157; called by muse, mutect2, varscan2
- ALG11 | c.637C>G p.Q213E | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1342806713, COSV73000751; called by muse, mutect2, varscan2
- ALG11 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73000743, COSV73000752; called by muse, mutect2, varscan2
- AMMECR1L | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.549); catalogued as COSV55761432; called by muse, mutect2, varscan2
- AMOTL1 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100504467, COSV58565049; called by muse, mutect2
- ANKH | c.638A>G p.Y213C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52484069; called by muse, mutect2, varscan2
- ANKRD11 | c.3157G>C p.D1053H | Missense Mutation (SNP) | VAF 64/102 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as COSV56367190; called by muse, mutect2, varscan2
- ANKRD12 | c.4606G>T p.D1536Y | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.594); catalogued as COSV50836791; called by muse, mutect2, varscan2
- ANLN | c.1069C>G p.Q357E | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV56074099; called by muse, mutect2, varscan2
- ANO1 | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); catalogued as COSV60287477; called by muse, mutect2, varscan2
- AP4E1 | c.1792G>T p.E598* | Nonsense Mutation (SNP) | VAF 34/121 reads (28%) | catalogued as COSV99956702; called by muse, mutect2, varscan2
- APOB | c.10424G>C p.G3475A | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51945176; called by muse, mutect2, varscan2
- ARHGAP19 | c.1403C>G p.S468C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV57394610; called by muse, mutect2, varscan2
- ARHGAP21 | c.4306G>A p.E1436K | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57609268; called by muse, mutect2, varscan2
- ARID1A | c.6212T>C p.L2071S | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61384061; called by muse, mutect2, varscan2
- ARL4D | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.327); catalogued as rs1290557660, COSV60721741; called by muse, mutect2, varscan2
- ATP10A | c.4004G>A p.G1335E | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63520972; called by muse, mutect2, varscan2
- ATP2B3 | c.1066G>C p.E356Q | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV54855792; called by muse, mutect2, varscan2
- AUTS2 | c.2136C>G p.F712L | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.595); catalogued as COSV61392040, COSV61420254; called by muse, mutect2, varscan2
- B4GALT4 | c.588C>A p.D196E | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63296207; called by muse, mutect2, varscan2
- BBS7 | c.1191C>G p.I397M | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as COSV52658394; called by muse, mutect2, varscan2
- BCORL1 | c.742C>G p.P248A | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.235); catalogued as COSV54402172; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4507G>A p.D1503N | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.271); catalogued as COSV63246334; called by muse, mutect2, varscan2
- BLM | c.182G>A p.R61K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as COSV61925915, COSV61927721; called by muse, mutect2, varscan2
- BOD1L1 | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV50033643; called by muse, mutect2, varscan2
- C11orf16 | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.187); catalogued as COSV58168489; called by muse, mutect2, varscan2
- C1orf146 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV64861160; called by muse, mutect2, varscan2
- C3orf14 | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs989428492, COSV51707300; called by muse, mutect2, varscan2
- C3orf56 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs376315163; called by muse, mutect2
- CAGE1 | c.1189C>T p.Q397* (on ENST00000512086; = p.Q261* on NM_205864.3) | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | catalogued as rs1339323342, COSV99699751; called by muse, mutect2, varscan2
- CAMSAP2 | c.831G>C p.L277F (on ENST00000236925 / NM_001297707.2; = p.L266F on NM_203459.3) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV52674592; called by muse, mutect2, varscan2
- CAPN2 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.68); catalogued as COSV54338121; called by muse, mutect2, varscan2
- CBY1 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.939); catalogued as COSV53264450; called by muse, mutect2, varscan2
- CCDC180 | c.2452G>C p.E818Q | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV63829183, COSV63833088; called by muse, mutect2, varscan2
- CCDC38 | c.1461G>A p.M487I | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60184121; called by muse, mutect2, varscan2
- CCR4 | c.438G>C p.L146F | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV58382258, COSV58383170; called by muse, mutect2, varscan2
- CDK10 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.817); catalogued as rs1295393303, COSV58415448; called by muse, mutect2, varscan2
- CEP131 | c.716C>G p.S239* | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | catalogued as COSV99487774, COSV99488398; called by muse, mutect2, varscan2
- CEP192 | c.1934C>T p.S645L | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as rs1037274899, COSV58068123; called by muse, mutect2, varscan2
- CEP89 | c.2270T>G p.L757R | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV59866351; called by muse, mutect2, varscan2
- CHTF18 | c.1886C>T p.S629L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as rs776463105, COSV50210795; called by muse, mutect2, varscan2
- CLEC4M | c.74G>C p.R25T | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.599); catalogued as COSV50222106; called by muse, mutect2, varscan2
- CLPTM1L | c.1269C>G p.I423M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.088); catalogued as COSV57991831; called by muse, mutect2, varscan2
- CNBD2 | c.307G>C p.E103Q | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV100839093, COSV62587522; called by muse, mutect2, varscan2
- CNTNAP4 | c.2758G>A p.G920R | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56692566; called by muse, mutect2, varscan2
- COIL | c.1543C>G p.L515V | Missense Mutation (SNP) | VAF 61/237 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.508); catalogued as COSV53594065, COSV53594554, COSV53596635; called by muse, varscan2
- COL17A1 | c.4123G>T p.E1375* | Nonsense Mutation (SNP) | VAF 29/82 reads (35%) | catalogued as COSV100211792; called by muse, mutect2, varscan2
- COL6A6 | c.3057G>A p.M1019I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.284); catalogued as COSV62032212; called by muse, mutect2, varscan2
- CROT | c.548-1G>C p.X183_splice | Splice Site (SNP) | VAF 40/89 reads (45%) | catalogued as COSV58975404; called by muse, mutect2, varscan2
- CRYBG3 | c.6451G>A p.E2151K | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.889); catalogued as rs143958468; called by muse, mutect2, varscan2
- CSMD2 | c.5363C>G p.S1788* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99590899; called by muse, mutect2, varscan2
- CSNK1E | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as rs1322444471, COSV63290829, COSV63291744; called by muse, mutect2, varscan2
- CTTNBP2 | c.692T>C p.L231P | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1250379218, COSV50435388; called by muse, mutect2, varscan2
- CYP24A1 | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.824); catalogued as rs1256208350, CM148911, COSV53775875; called by muse, mutect2, varscan2
- CYP2A6 | c.1337G>A p.R446K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as COSV99991707; called by mutect2, varscan2
- CYP2A7 | c.1337G>A p.R446K | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.156); catalogued as rs768997550, COSV52501369; called by muse, mutect2
- CYP3A43 | c.403C>G p.P135A | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55937207; called by muse, mutect2, varscan2
- DALRD3 | c.1369C>G p.P457A (on ENST00000341949 / NM_001009996.3; = p.P290A on NM_018114.5) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.171); catalogued as COSV58246468; called by muse, mutect2, varscan2
- DCAKD | c.632C>A p.T211K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as COSV60832060; called by muse, mutect2, varscan2
- DCDC1 | c.979A>G p.I327V | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs761729640, COSV60851548; called by muse, mutect2, varscan2
- DDX11 | c.2337G>A p.M779I (on ENST00000545668 / NM_152438.2; = p.M729I on NM_004399.3) | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52508125; called by muse, mutect2, varscan2
- DDX21 | c.1312C>G p.Q438E | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV62556241; called by muse, mutect2, varscan2
- DERL3 | c.286G>A p.D96N | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV99320271; called by muse, mutect2
- DNAH1 | c.12172C>T p.Q4058* | Nonsense Mutation (SNP) | VAF 18/39 reads (46%) | catalogued as COSV99964047; called by muse, mutect2, varscan2
- DOCK2 | c.3988G>A p.E1330K | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV56975232; called by muse, mutect2, varscan2
- EFCAB14 | c.994G>C p.D332H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.755); catalogued as COSV64240127; called by muse, mutect2, varscan2
- EHD1 | c.1020G>C p.Q340H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV57735863; called by muse, mutect2, varscan2
- EIF2AK4 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.585); catalogued as COSV55471866; called by muse, mutect2, varscan2
- ERBB2 | c.1785C>A p.F595L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV54076688; called by muse, mutect2, varscan2
- ERC2 | c.2740G>A p.D914N | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1018775914, COSV55645976; called by muse, mutect2
- ESCO1 | c.212C>G p.S71* | Nonsense Mutation (SNP) | VAF 38/151 reads (25%) | catalogued as rs1384971065, COSV52523073; called by muse, mutect2, varscan2
- ESR1 | c.1765G>C p.E589Q | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.321); catalogued as COSV52797526; called by muse, mutect2
- ETV5 | c.643G>T p.E215* | Nonsense Mutation (SNP) | VAF 25/75 reads (33%) | catalogued as COSV100112128; called by muse, mutect2, varscan2
- FAM120A | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | catalogued as COSV99465605; called by muse, mutect2, varscan2
- FAM8A1 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.123); catalogued as rs1366000323, COSV52580283, COSV52580559; called by muse, mutect2, varscan2
- FANCI | c.3803C>G p.S1268C (on ENST00000310775 / NM_001376911.1; = p.S1208C on NM_018193.3) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51523462; called by muse, mutect2, varscan2
- FGFRL1 | c.1355C>T p.S452F | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.095); catalogued as rs1260461436, COSV53258588; called by muse, mutect2
- FNBP4 | c.1415C>T p.S472F | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55450729, COSV99771594; called by muse, mutect2, varscan2
- FTL | c.100C>G p.L34V | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.519); catalogued as rs11553192, COSV53171177; called by muse, mutect2
- FUBP1 | c.647G>C p.G216A | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53935290; called by muse, mutect2
- FUS | c.1546G>C p.E516Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.058); catalogued as COSV54218851, COSV99568743; called by muse, mutect2, varscan2
- GBP5 | c.34T>A p.C12S | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV58593758; called by muse, mutect2
- GC | c.6G>C p.K2N | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV56738660; called by muse, mutect2, varscan2
- GEMIN8 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.067); catalogued as rs1487468361, COSV60551149; called by muse, mutect2, varscan2
- GJD4 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV58703012; called by muse, mutect2, varscan2
- GMPS | c.2051C>G p.S684* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99903178; called by muse, mutect2, varscan2
- GOLGA1 | c.2086G>C p.E696Q | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.686); catalogued as COSV52346852; called by muse, mutect2, varscan2
- GOLGA4 | c.720G>A p.M240I | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1391533228, COSV62712435; called by muse, mutect2, varscan2
- GP2 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV100221547, COSV56895610; called by muse, mutect2, varscan2
- GPR83 | c.1063G>C p.E355Q | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); catalogued as COSV54719892; called by muse, mutect2, varscan2
- GTF2I | c.1345G>C p.D449H (on ENST00000573035 / NM_032999.4; = p.D408H on NM_001518.5) | Missense Mutation (SNP) | VAF 45/139 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV60402725; called by muse, mutect2, varscan2
- GTF3C5 | c.949C>G p.Q317E | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59601231; called by muse, mutect2, varscan2
- GUCY2C | c.246C>A p.F82L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as COSV53793354; called by muse, mutect2, varscan2
- H4C13 | c.192G>C p.E64D | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as COSV60694758; called by muse, mutect2, varscan2
- HACL1 | c.693G>C p.E231D | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV58255648; called by muse, mutect2, varscan2
- HEXIM1 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs756384069, COSV60177346; called by muse, mutect2, varscan2
- HGS | c.1751C>T p.S584L | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs538920453, COSV61269413; called by muse, mutect2, varscan2
- HIRA | c.203A>G p.N68S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as COSV54277659; called by muse, mutect2, varscan2
- HMGCS1 | c.85C>G p.Q29E | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV57291025, COSV57291912; called by muse, mutect2, varscan2
- HSD17B7 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753578254, COSV54419260; called by muse, mutect2, varscan2
- HSP90AA1 | c.419C>G p.S140C | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53490338, COSV99355157; called by muse, varscan2
- HSPA1L | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.472); catalogued as COSV65150237, COSV65150938; called by muse, mutect2, varscan2
- IBTK | c.3706C>G p.Q1236E | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV60394863; called by muse, mutect2, varscan2
- ICA1L | c.662C>T p.S221F | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64174155; called by muse, mutect2, varscan2
- IFNL3 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 25/82 reads (30%) | catalogued as COSV69830025; called by muse, mutect2, varscan2
- IL32 | c.605C>T p.S202L (on ENST00000396890 / NM_001308078.4; = p.S156L on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV50404024, COSV50404792; called by muse, mutect2, varscan2
- IMMT | c.1945G>T p.D649Y | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54477814, COSV54481775; called by muse, mutect2, varscan2
- INO80 | c.1974G>C p.K658N | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62740754; called by muse, mutect2, varscan2
- ITGA4 | c.2340-2A>T p.X780_splice | Splice Site (SNP) | VAF 11/49 reads (22%) | catalogued as COSV67898349; called by muse, mutect2, varscan2
- IZUMO2 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV53230147; called by muse, mutect2, varscan2
- KAT2B | c.1527G>C p.K509N | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV55432454; called by muse, mutect2, varscan2
- KAZN | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.678); catalogued as rs773002622, COSV63207903; called by muse, mutect2, varscan2
- KCNH1 | c.480C>A p.S160R | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV55069632, COSV55090729; called by muse, mutect2, varscan2
- KCNK4 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV60453933; called by muse, varscan2
- KCNK4 | c.312C>T p.I104= | Splice Region (SNP) | VAF 5/34 reads (15%) | catalogued as rs199677022, COSV60453768; called by muse, varscan2
- KCNQ3 | c.2149C>T p.P717S | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV101196176; called by muse, mutect2
- KDM6A | c.3148del p.E1050Kfs*33 | Frame Shift Del (DEL) | VAF 20/44 reads (45%) | catalogued as COSV65043361, COSV65045970; called by pindel, varscan2
- KDM6A | c.3154G>T p.E1052* | Nonsense Mutation (SNP) | VAF 22/35 reads (63%) | catalogued as COSV65038777, COSV65040016, COSV65045978; called by muse, varscan2
- KIAA0232 | c.979G>T p.G327W | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56927562, COSV56930503; called by muse, mutect2, varscan2
- KIAA0232 | c.3545C>G p.S1182C | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs572591231, COSV100300732, COSV56927569; called by muse, mutect2, varscan2
- KIAA0319L | c.3028G>A p.D1010N | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs750623856, COSV57845436; called by muse, mutect2, varscan2
- KIAA1549 | c.2273C>A p.S758* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99650894; called by muse, mutect2, varscan2
- KIDINS220 | c.731C>G p.S244* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as rs1208602751, COSV56757564, COSV99875795; called by muse, mutect2, varscan2
- KLHDC2 | c.566G>A p.R189K | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.956); catalogued as COSV100027150, COSV53588037; called by muse, mutect2, varscan2
- KRT19 | c.721C>G p.P241A | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs770022377, COSV54180984, COSV54181566; called by muse, varscan2
- KRT36 | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV60204225; called by muse, mutect2, varscan2
- KRT36 | c.77C>G p.S26C | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs781275139, COSV60204234; called by muse, mutect2, varscan2
- KRTCAP2 | c.328C>T p.Q110* (on ENST00000497317; = p.I108= on NM_173852.4) | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | catalogued as COSV55279765; called by muse, mutect2, varscan2
- LAMA3 | c.3307C>T p.L1103F | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV58074794; called by muse, mutect2, varscan2
- LAMA3 | c.4021G>C p.E1341Q | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.92); catalogued as COSV58074802; called by muse, mutect2, varscan2
- LAMB4 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.106); catalogued as rs150197498; called by muse, mutect2, varscan2
- LCLAT1 | c.990G>C p.Q330H | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.19); catalogued as COSV58375981; called by muse, mutect2, varscan2
- LETMD1 | c.915G>T p.S305= | Splice Region (SNP) | VAF 19/49 reads (39%) | catalogued as COSV50398638; called by muse, varscan2
- LMNB1 | c.1390C>T p.Q464* | Nonsense Mutation (SNP) | VAF 8/20 reads (40%) | catalogued as COSV99745941; called by muse, mutect2, varscan2
- LRRC37B | c.1282G>C p.E428Q | Missense Mutation (SNP) | VAF 48/182 reads (26%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.486); catalogued as COSV58953806; called by muse, mutect2, varscan2
- LRRK1 | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.469); catalogued as COSV52621564; called by muse, mutect2, varscan2
- LSP1 | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as COSV100289203; called by muse, mutect2
- MACROD2 | c.283C>G p.L95V | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV54020979; called by muse, mutect2, varscan2
- MAIP1 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.264); catalogued as COSV54461223, COSV54461564, COSV99705162; called by muse, mutect2, varscan2
- MAP2K6 | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as rs1467832694, COSV63007102; called by muse, mutect2, varscan2
- MAST2 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); catalogued as COSV63620268; called by muse, mutect2, varscan2
- MCPH1 | c.2416G>A p.A806T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.096); catalogued as COSV60917188; called by muse, mutect2, varscan2
- MDN1 | c.1579G>C p.E527Q | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV65526390; called by muse, mutect2, varscan2
- MDN1 | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs758213531, COSV65526397; called by muse, mutect2, varscan2
- MFAP3 | c.441G>C p.M147I | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV59456998; called by muse, mutect2, varscan2
- MIB2 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as rs1330039372, COSV100598925; called by muse, mutect2
- MICAL2 | c.2780G>C p.R927T | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.038); catalogued as COSV56321261, COSV56323517; called by muse, mutect2, varscan2
- MINAR1 | c.2026G>C p.E676Q | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.805); catalogued as rs749709523, COSV59585053; called by muse, mutect2, varscan2
- MKI67 | c.4015G>A p.E1339K | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64075712; called by muse, mutect2, varscan2
- MKI67 | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV64075714; called by muse, mutect2, varscan2
- MOCOS | c.2126C>G p.S709* | Nonsense Mutation (SNP) | VAF 27/87 reads (31%) | catalogued as rs938716384, COSV99733469; called by muse, mutect2, varscan2
- MPND | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV53658758; called by muse, mutect2, varscan2
- MRPL30 | c.230G>C p.R77T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.861); catalogued as COSV100585452, COSV57667417; called by muse, mutect2, varscan2
- MRTFA | c.638C>G p.S213C | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.866); catalogued as COSV62935210; called by muse, mutect2, varscan2
- MSL1 | c.1540G>A p.E514K (on ENST00000398532 / NM_001365919.1; = p.E251K on NM_001012241.2) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV59899562; called by muse, mutect2
- MTBP | c.2106G>C p.L702F | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV59964908; called by muse, mutect2, varscan2
- MTIF2 | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV55051997, COSV55053022; called by muse, varscan2
- MUC17 | c.12945G>A p.E4315= | Splice Region (SNP) | VAF 17/45 reads (38%) | catalogued as COSV60297207; called by muse, mutect2, varscan2
- MX1 | c.1582G>T p.E528* | Nonsense Mutation (SNP) | VAF 26/104 reads (25%) | catalogued as COSV99912655; called by muse, mutect2, varscan2
- MYH1 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56853540; called by muse, varscan2
- MYH10 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 64/120 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.903); catalogued as COSV52606784; called by muse, mutect2, varscan2
- MYLIP | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV62767304; called by muse, mutect2, varscan2
- MYO15A | c.10558C>A p.L3520I | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV52761678; called by muse, mutect2, varscan2
- MYO7B | c.1031C>G p.S344* | Nonsense Mutation (SNP) | VAF 8/12 reads (67%) | catalogued as COSV101268204, COSV101268365; called by muse, mutect2, varscan2
- MYRIP | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV56876686; called by mutect2, varscan2
- MZF1 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.558); catalogued as COSV53042574; called by muse, mutect2, varscan2
- N4BP3 | c.575C>A p.S192Y | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV51065240; called by muse, mutect2, varscan2
- NAGLU | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761107171, COSV56793908, COSV56795659; called by muse, mutect2, varscan2
- NAV1 | c.1194G>C p.K398N | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV55222319; called by muse, mutect2, varscan2
- NBEAL1 | c.4007C>T p.S1336F | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as COSV71375138; called by muse, mutect2, varscan2
- NHS | c.4040C>G p.S1347* | Nonsense Mutation (SNP) | VAF 21/33 reads (64%) | catalogued as COSV101196632; called by muse, mutect2, varscan2
- NLRP9 | c.384G>A p.M128I | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60466023; called by muse, mutect2, varscan2
- NPAS3 | c.309G>T p.M103I (on ENST00000356141 / NM_001164749.2; = p.M73I on NM_022123.3) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.286); catalogued as COSV58099218; called by muse, mutect2, varscan2
- NPIPB15 | c.926C>G p.S309C | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1273532579, COSV70437146, COSV70438029; called by muse, mutect2
- NPR2 | c.2543G>A p.R848Q | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as rs368849630; called by muse, mutect2, varscan2
- NR1I2 | c.1293C>G p.I431M | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.2); catalogued as COSV51779941; called by muse, mutect2, varscan2
- NR5A1 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs769207009, CM156317, COSV65294583; called by muse, mutect2, varscan2
- NTNG2 | c.1223-1G>A p.X408_splice | Splice Site (SNP) | VAF 9/29 reads (31%) | catalogued as COSV62367991; called by muse, mutect2, varscan2
- NUP188 | c.3755G>C p.S1252T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV65363672; called by muse, mutect2
- NWD1 | c.4493G>A p.R1498Q | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); catalogued as rs756526921, COSV100343583, COSV60344240; called by muse, mutect2, varscan2
- OBSCN | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.452); catalogued as rs778906218, COSV52804934; called by muse, mutect2, varscan2
- OGFRL1 | c.617G>C p.G206A | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64972303; called by muse, mutect2, varscan2
- OPTN | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53812159; called by muse, mutect2, varscan2
- OR10H4 | c.256C>A p.L86M | Missense Mutation (SNP) | VAF 10/302 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as COSV59062464; called by muse, mutect2
- OR10J5 | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58387085; called by muse, mutect2, varscan2
- OR10T2 | c.313T>C p.F105L | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as COSV57782502; called by muse, mutect2, varscan2
- OR13A1 | c.759G>C p.Q253H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.726); catalogued as COSV65572980; called by muse, mutect2, varscan2
- OR14C36 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs1476519764, COSV58600960, COSV58601720; called by muse, mutect2, varscan2
- OR2M3 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT tolerated (0.95); PolyPhen benign (0.012); catalogued as rs547891650, COSV71759184, COSV71759200; called by muse, mutect2, varscan2
- OR4A47 | c.96C>G p.F32L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.031); catalogued as rs758038674, COSV101487069; called by muse, mutect2, varscan2
- OR56A3 | c.477G>A p.M159I | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV61569712; called by muse, mutect2, varscan2
- OR5H6 | c.214C>T p.H72Y (on ENST00000642105; = p.H56Y on NM_001005479.2) | Missense Mutation (SNP) | VAF 80/235 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV67351458; called by muse, mutect2, varscan2
- OR6C75 | c.410G>C p.R137T | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.456); catalogued as COSV58553120; called by muse, mutect2, varscan2
- OR6M1 | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58434258; called by muse, mutect2, varscan2
- PAPSS2 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV63264443; called by muse, mutect2, varscan2
- PARP15 | c.1921C>G p.H641D (on ENST00000464300 / NM_001113523.3; = p.H407D on NM_152615.2) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV59974000; called by muse, mutect2, varscan2
- PBX4 | c.773C>G p.S258C | Missense Mutation (SNP) | VAF 111/309 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52060890, COSV52063107; called by muse, mutect2, varscan2
- PCDH11X | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.602); catalogued as COSV100012064; called by muse, mutect2, varscan2
- PCDHB5 | c.1322C>G p.S441C | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV50660420, COSV50661708, COSV99167661; called by muse, mutect2, varscan2
- PCNT | c.591C>G p.I197M | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs559031201, COSV64031084; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDE1C | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV58522071; called by muse, mutect2, varscan2
- PDZD2 | c.2394G>C p.L798F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56866681; called by muse, mutect2, varscan2
- PHF1 | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV53384692; called by muse, mutect2, varscan2
- PI4KA | c.1833G>C p.L611F | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as COSV55417874; called by muse, mutect2, varscan2
- PI4KA | c.1181C>G p.S394C | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.401); catalogued as COSV55413908, COSV55417896; called by muse, mutect2, varscan2
- PIGO | c.2006G>A p.W669* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99956709; called by muse, mutect2
- PLCB4 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs768015317, COSV53811096; called by muse, mutect2, varscan2
- PLEKHA5 | c.3094G>C p.E1032Q | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.146); catalogued as COSV54707839; called by muse, mutect2, varscan2
- PLVAP | c.1111G>C p.E371Q | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT tolerated (0.4); PolyPhen benign (0.058); catalogued as COSV53086635; called by muse, mutect2, varscan2
- PLXNA2 | c.4438G>A p.E1480K | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1269275813, COSV65437873; called by muse, mutect2, varscan2
- POLN | c.863C>T p.S288F | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV67026620; called by muse, mutect2, varscan2
- POLR2F | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.024); catalogued as COSV50778402; called by muse, mutect2, varscan2
- POMZP3 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 65/238 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.727); catalogued as COSV51886281, COSV99300545; called by muse, mutect2, varscan2
- PPP2R5D | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1437917476, COSV55151229; called by muse, mutect2, varscan2
- PRDX1 | c.317C>G p.S106* | Nonsense Mutation (SNP) | VAF 48/122 reads (39%) | catalogued as COSV99423607; called by muse, mutect2, varscan2
- PRDX1 | c.126C>G p.F42L | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.386); catalogued as rs1309588088, COSV53113482; called by muse, mutect2, varscan2
- PRKD2 | c.1776G>C p.E592D | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1197811373, COSV52185179, COSV52187662, COSV52188578; called by muse, mutect2, varscan2
- PROX1 | c.1825G>C p.D609H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54781632, COSV99800227; called by muse, mutect2, varscan2
- PRR22 | c.827G>T p.R276I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV57832860; called by muse, mutect2, varscan2
- PSEN2 | c.934C>G p.Q312E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV60917440, COSV60917501; called by muse, mutect2, varscan2
- PTK2 | c.400C>G p.L134V | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV61787263, COSV61789489; called by muse, mutect2, varscan2
- PTPN22 | c.905C>G p.S302C | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV63085976; called by muse, mutect2, varscan2
- PTPRZ1 | c.1778C>T p.T593I | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as COSV66442161; called by muse, mutect2, varscan2
- RABAC1 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.472); catalogued as COSV55771163; called by muse, mutect2, varscan2
- RB1 | c.2391dup p.R798Tfs*17 | Frame Shift Ins (INS) | VAF 30/84 reads (36%) | catalogued as CI012716, COSV57300252, COSV57321960; called by mutect2, pindel, varscan2
- RBL1 | c.6C>G p.F2L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs1436289644, COSV100727075; called by muse, mutect2, varscan2
- RBP2 | c.15G>C p.Q5H | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV51672861; called by muse, mutect2, varscan2
- RELCH | c.1090G>T p.D364Y | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV56889327; called by muse, mutect2, varscan2
- RFTN1 | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV61921480; called by muse, mutect2, varscan2
- RMDN3 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as rs1320647808, COSV53024209; called by muse, mutect2, varscan2
- RNF121 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV62316883, COSV62317376; called by muse, mutect2, varscan2
- RNF169 | c.1507C>T p.H503Y | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55134447; called by muse, mutect2, varscan2
- RNF19A | c.1367G>A p.R456Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1563833600, COSV100348192, COSV61994184; called by muse, mutect2, varscan2
- RNF44 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1422247683, COSV99221913; called by muse, mutect2, varscan2
- ROS1 | c.374C>G p.S125C | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs775119219, COSV63855582, COSV63857369, COSV63859049; called by muse, mutect2, varscan2
- RTN4 | c.1693G>T p.E565* | Nonsense Mutation (SNP) | VAF 36/101 reads (36%) | catalogued as COSV58275032; called by muse, mutect2, varscan2
- RTN4 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV58271498; called by muse, mutect2, varscan2
- RYR3 | c.3546G>C p.E1182D | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV66802011; called by muse, mutect2, varscan2
- SAMD14 | c.513C>A p.D171E | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.99); catalogued as COSV53309544, COSV53310728; called by muse, mutect2, varscan2
- SERBP1 | c.560C>G p.S187C | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV63412979; called by muse, mutect2, varscan2
- SERPINB2 | c.933G>T p.Q311H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV55093806; called by muse, mutect2, varscan2
- SERPINB5 | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs374163653; called by muse, mutect2, varscan2
- SETDB1 | c.3436G>C p.E1146Q | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as COSV54989112; called by muse, mutect2, varscan2
- SHBG | c.1003C>A p.P335T | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.51); PolyPhen benign (0.039); catalogued as COSV61412226; called by muse, mutect2, varscan2
- SLC25A22 | c.277C>G p.Q93E | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.103); catalogued as rs1232725403, COSV100204213; called by muse, mutect2
- SLC26A8 | c.893G>A p.R298K | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.52); PolyPhen benign (0.027); catalogued as COSV62886941; called by muse, mutect2, varscan2
- SLC32A1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.011); catalogued as rs1347085642, COSV54147765; called by muse, mutect2, varscan2
- SLC39A12 | c.1105T>C p.Y369H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs951456225, COSV66200991; called by muse, mutect2, varscan2
- SLC5A12 | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54823503; called by muse, mutect2, varscan2
- SLFN11 | c.116G>A p.R39K | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV104413347, COSV57699853; called by muse, mutect2, varscan2
- SLITRK1 | c.1312C>G p.L438V | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV65676869; called by muse, mutect2, varscan2
- SLITRK6 | c.312G>C p.E104D | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV68391066; called by muse, mutect2, varscan2
- SMC4 | c.141G>A p.E47= | Splice Region (SNP) | VAF 32/121 reads (26%) | catalogued as rs1490073814, COSV58450367; called by muse, mutect2, varscan2
- SNX17 | c.508G>T p.D170Y | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV52009277; called by muse, mutect2, varscan2
- SNX17 | c.606G>T p.R202S | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV52009293; called by muse, mutect2, varscan2
- SNX17 | c.691G>C p.D231H | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52009303; called by muse, mutect2, varscan2
- SNX17 | c.1397G>A p.G466E | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52009322; called by muse, mutect2, varscan2
- SPATA25 | c.684G>C p.*228Yext*9 | Nonstop Mutation (SNP) | VAF 48/144 reads (33%) | catalogued as COSV99509896; called by muse, mutect2, varscan2
- SPATS1 | c.379C>G p.P127A | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV55824242; called by muse, mutect2, varscan2
- SPOCD1 | c.3249C>G p.I1083M | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV57095076, COSV57098277; called by muse, mutect2, varscan2
- SPTAN1 | c.5617C>G p.Q1873E | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as COSV63988844; called by muse, mutect2, varscan2
- SRA1 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV60365983; called by muse, mutect2, varscan2
- SRCIN1 | c.2281G>T p.E761* (on ENST00000621492; = p.E727* on NM_025248.3) | Nonsense Mutation (SNP) | VAF 26/126 reads (21%) | catalogued as rs1346757020; called by muse, mutect2, varscan2
- SRD5A3 | c.313C>G p.P105A | Missense Mutation (SNP) | VAF 62/106 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV51712865; called by muse, mutect2, varscan2
- STAT1 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.023); catalogued as COSV100738668; called by muse, mutect2
- STAU1 | c.284C>G p.P95R (on ENST00000371856 / NM_001319135.1; = p.P14R on NM_004602.3) | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); catalogued as COSV61461610; called by muse, mutect2, varscan2
- STK32B | c.1244G>C p.*415Sext*80 | Nonstop Mutation (SNP) | VAF 7/11 reads (64%) | catalogued as COSV99285976; called by muse, mutect2, varscan2
- STOML2 | c.23G>A p.G8D | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as rs761928176, COSV59717075, COSV59717101; called by muse, mutect2, varscan2
- STT3B | c.906A>T p.L302F | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV55504629; called by muse, mutect2, varscan2
- SULF1 | c.2306C>T p.T769M | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.961); catalogued as rs957456132, COSV52672141; called by muse, mutect2
- SULT2A1 | c.670A>G p.K224E | Missense Mutation (SNP) | VAF 63/158 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV55765677; called by muse, mutect2, varscan2
- SYNGR2 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.603); catalogued as rs9889851, COSV99857400; called by muse, mutect2, varscan2
- SZT2 | c.4589C>T p.S1530L (on ENST00000634258 / NM_001365999.1; = p.S1473L on NM_015284.4) | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV65172321; called by muse, mutect2, varscan2
- TAF1L | c.5417G>C p.R1806T | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.195); catalogued as COSV54265834, COSV54266320; called by muse, mutect2, varscan2
- TAF1L | c.4561G>A p.D1521N | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.171); catalogued as rs1201639406, COSV54265846; called by muse, mutect2, varscan2
- TANC1 | c.3974G>A p.G1325E | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as COSV55093068; called by muse, mutect2, varscan2
- TBC1D5 | c.782C>A p.A261D | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53765019; called by muse, mutect2, varscan2
- TBKBP1 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs375276695, COSV100659177; called by muse, mutect2, varscan2
- TFCP2L1 | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV55293551; called by muse, mutect2, varscan2
- TGM4 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1393206647, COSV56095382; called by muse, mutect2, varscan2
- TGOLN2 | c.941C>G p.S314C | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56406997; called by muse, mutect2, varscan2
- THAP7 | c.720G>C p.W240C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99301851; called by muse, mutect2, varscan2
- TMC6 | c.2169C>G p.F723L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as COSV59810274; called by muse, mutect2, varscan2
- TMCO4 | c.37C>G p.Q13E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as COSV53872305, COSV99615488, COSV99616333; called by muse, mutect2
- TRIM73 | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.053); catalogued as COSV51903916; called by muse, varscan2
- TRIM73 | c.73G>T p.E25* | Nonsense Mutation (SNP) | VAF 15/75 reads (20%) | catalogued as COSV99303075; called by muse, varscan2
- TRMT12 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV60777571; called by muse, mutect2, varscan2
- TRPV4 | c.2359C>A p.H787N | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.272); catalogued as COSV55683256, COSV55683974; called by muse, mutect2, varscan2
- TSPAN18 | c.745T>C p.*249Qext*7 | Nonstop Mutation (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100370900; called by muse, mutect2, varscan2
- TTC30B | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 59/211 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV68809683; called by muse, mutect2, varscan2
- TTLL9 | c.903C>G p.I301M | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.553); catalogued as COSV100207221, COSV60594798; called by muse, mutect2, varscan2
- UBE4A | c.643C>T p.L215F | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV52806010; called by muse, mutect2, varscan2
- UBR4 | c.6369C>A p.F2123L | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV64395214; called by muse, mutect2, varscan2
- UGGT2 | c.689C>T p.S230F | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV65025757; called by muse, mutect2, varscan2
- UNC93B1 | c.635C>G p.S212C | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV57097599, COSV57100172, COSV57100967; called by muse, varscan2
- USP29 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 45/109 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.1); catalogued as COSV54141680, COSV54141879; called by muse, mutect2, varscan2
- USP30 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.167); catalogued as COSV57447982; called by muse, mutect2, varscan2
- USP53 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.16); catalogued as COSV56796484; called by muse, mutect2, varscan2
- UTRN | c.1969C>T p.R657C | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as rs770003496, COSV62335160; called by muse, mutect2, varscan2
- VIRMA | c.5426C>A p.S1809Y | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52586476, COSV52588754; called by muse, mutect2, varscan2
- VPS35L | c.2359C>A p.P787T | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1255365249, COSV51987821; called by muse, mutect2, varscan2
- WDR18 | c.355C>G p.R119G | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV52122791, COSV99243133; called by muse, mutect2, varscan2
- WDR6 | c.3365G>C p.*1122Sext*86 | Nonstop Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as COSV100556145, COSV100556451; called by muse, mutect2, varscan2
- WDR73 | c.426C>G p.F142L | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as COSV62411351; called by muse, mutect2, varscan2
- WHAMM | c.2203C>T p.P735S | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.41); catalogued as rs1319784977, COSV54498097; called by muse, mutect2, varscan2
- WIPF2 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 16/106 reads (15%) | catalogued as rs1176500354, COSV100063621; called by muse, mutect2, varscan2
- XBP1 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53274012; called by muse, varscan2
- YTHDF1 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as rs773451524, COSV100945535, COSV64833553; called by muse, mutect2, varscan2
- YTHDF2 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as COSV65723839; called by muse, mutect2, varscan2
- ZBED9 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.017); catalogued as COSV71729644; called by muse, mutect2, varscan2
- ZFYVE26 | c.2447G>C p.R816T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.543); catalogued as COSV61331585; called by muse, mutect2, varscan2
- ZFYVE26 | c.2339G>A p.R780Q | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs142041405; called by muse, mutect2, varscan2
- ZKSCAN3 | c.1249C>T p.H417Y | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52853566; called by muse, mutect2, varscan2
- ZMYM6 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.041); catalogued as COSV64121926; called by muse, mutect2, varscan2
- ZNF304 | c.539C>G p.S180C | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.628); catalogued as COSV56585651, COSV56585708; called by muse, mutect2, varscan2
- ZNF484 | c.1526C>G p.S509* | Nonsense Mutation (SNP) | VAF 5/109 reads (5%) | catalogued as COSV100214694, COSV100214869; called by muse, mutect2
- ZNF484 | c.148C>G p.Q50E | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.078); catalogued as COSV60258947; called by muse, mutect2, varscan2
- ZNF506 | c.762G>C p.E254D | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as COSV71354543; called by muse, mutect2, varscan2
- ZNF527 | c.1637G>A p.R546K | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.169); catalogued as COSV62229863, COSV62233205; called by muse, mutect2, varscan2
- ZNF750 | c.1186G>T p.E396* | Nonsense Mutation (SNP) | VAF 31/153 reads (20%) | catalogued as COSV99489786; called by muse, mutect2, varscan2
- ZNF750 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as rs377565207, COSV53961393, COSV53961753; called by muse, mutect2, varscan2
- ZNF99 | c.2069C>G p.S690* | Nonsense Mutation (SNP) | VAF 46/125 reads (37%) | catalogued as COSV101233841, COSV68054546; called by muse, mutect2, varscan2
- ACACA | c.64C>G p.Q22E | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPR179 | c.3283C>G p.L1095V (on ENST00000621958; = p.L1094V on NM_001004334.4) | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV6-21 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- KMT2D | c.5135del p.K1712Rfs*10 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- LCT | c.3016G>T p.G1006C | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- NBPF14 | c.8948G>C p.G2983A | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.273); called by mutect2, varscan2
- OR7A10 | c.417del p.Q139Hfs*13 | Frame Shift Del (DEL) | VAF 21/79 reads (27%) | called by mutect2, pindel, varscan2
- ADRA1A | c.432C>T p.L144= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs1420047651, COSV52370273; called by muse, mutect2, varscan2
- AFAP1 | c.732C>T p.I244= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as COSV61797472; called by muse, mutect2, varscan2
- ARHGEF35 | c.444G>A p.E148= | Silent (SNP) | VAF 6/40 reads (15%) | called by mutect2, varscan2
- ATAD3B | c.225G>A p.L75= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100426316, COSV58022346; called by muse, varscan2
- ATP2A1 | c.1488C>A p.V496= | Silent (SNP) | VAF 52/118 reads (44%) | catalogued as COSV63921789; called by muse, mutect2, varscan2
- ATP2B3 | c.1911G>A p.P637= | Silent (SNP) | VAF 20/26 reads (77%) | catalogued as rs189723972, COSV54840504; called by muse, mutect2, varscan2
- CACNA1B | c.1647C>T p.F549= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs764297799, COSV53126785; called by muse, mutect2, varscan2
- CACNA1B | c.3837G>A p.L1279= | Silent (SNP) | VAF 65/191 reads (34%) | catalogued as COSV53139144; called by muse, mutect2, varscan2
- CAMSAP2 | c.756G>C p.G252= (on ENST00000236925 / NM_001297707.2; = p.G241= on NM_203459.3) | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as COSV52674580; called by muse, mutect2, varscan2
- CBARP | c.981C>T p.F327= (on ENST00000382477; = p.F307= on NM_152769.3) | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1244856329, COSV53070545, COSV53070779; called by muse, mutect2, varscan2
- CCM2 | c.63C>T p.F21= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV51850179; called by muse, mutect2, varscan2
- CHD7 | c.5964G>A p.V1988= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV71113078; called by muse, mutect2, varscan2
- CNKSR3 | c.708G>C p.V236= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV101401368; called by muse, mutect2
- CNR1 | c.1227G>A p.R409= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV62990088; called by muse, mutect2, varscan2
- COP1 | c.2118G>A p.R706= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as rs543788653, COSV58172569; called by muse, mutect2, varscan2
- CTC1 | c.723G>A p.Q241= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as rs1275112523, COSV59854430; called by muse, mutect2, varscan2
- CYP7A1 | c.789C>A p.L263= | Silent (SNP) | VAF 50/112 reads (45%) | catalogued as COSV56964711; called by muse, mutect2, varscan2
- CYP7A1 | c.669C>A p.L223= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as COSV56964718; called by muse, mutect2, varscan2
- DIS3 | c.1785G>A p.L595= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV66707431; called by muse, mutect2, varscan2
- DNAH7 | c.8727C>T p.L2909= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs926836368, COSV56776520; called by muse, mutect2, varscan2
- DNMBP | c.4629C>T p.L1543= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as rs1462771637, COSV60630064; called by muse, mutect2, varscan2
- DNMT1 | c.1281C>T p.I427= | Silent (SNP) | VAF 20/94 reads (21%) | catalogued as rs767165265, COSV61581860; called by muse, mutect2, varscan2
- DTX3L | c.36C>T p.L12= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs1187052147, COSV56145079, COSV99950077; called by muse, mutect2, varscan2
- ERCC2 | c.1485C>T p.I495= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs758510144, COSV67262287; called by muse, mutect2, varscan2
- EZH2 | c.285C>T p.V95= | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as rs771848373, COSV57458197; called by muse, mutect2, varscan2
- FBXW2 | c.552C>T p.I184= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV61597647; called by muse, mutect2, varscan2
- FEM1B | c.1782G>A p.K594= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV60989171; called by muse, mutect2, varscan2
- FOXD4L4 | c.198G>A p.G66= | Silent (SNP) | VAF 26/158 reads (16%) | called by muse, mutect2, varscan2
- FXYD1 | c.144C>T p.F48= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs762504988, COSV54343680; called by muse, mutect2, varscan2
- GALNT16 | c.1533C>G p.G511= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV100546040, COSV61887004; called by muse, mutect2, varscan2
- GANC | c.1941C>G p.T647= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV58810642; called by muse, mutect2
- GCG | c.123C>T p.L41= | Silent (SNP) | VAF 41/151 reads (27%) | catalogued as COSV64961868; called by muse, mutect2, varscan2
- GPR171 | c.462C>T p.I154= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV56389024; called by muse, mutect2, varscan2
- HCN1 | c.273C>T p.Y91= | Silent (SNP) | VAF 3/34 reads (9%) | catalogued as rs1170637860, COSV100300090, COSV57521360; called by muse, mutect2
- IGKV3-7 | c.204C>T p.L68= | Silent (SNP) | VAF 26/84 reads (31%) | called by muse, mutect2
- ITGA2 | c.2721T>G p.S907= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV56864115; called by muse, mutect2, varscan2
- JCAD | c.1587G>A p.V529= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as COSV64760189, COSV64760919; called by muse, mutect2, varscan2
- JUP | c.1155G>A p.K385= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as COSV60279118; called by muse, mutect2
- KCNJ10 | c.150C>G p.L50= | Silent (SNP) | VAF 30/116 reads (26%) | catalogued as COSV63634461; called by muse, mutect2, varscan2
- KCNK4 | c.363C>A p.I121= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV60454855; called by muse, mutect2, varscan2
- LCMT1 | c.987G>A p.L329= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV66726310; called by muse, mutect2, varscan2
- LRIG2 | c.876C>G p.L292= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs1327260242, COSV63163265; called by muse, mutect2, varscan2
- LRRC30 | c.309G>A p.G103= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs754858511, COSV67302060; called by muse, mutect2, varscan2
- LTBP4 | c.4782C>A p.L1594= (on ENST00000308370 / NM_001042544.1; = p.L1557= on NM_003573.2) | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV52587000; called by muse, mutect2, varscan2
- MACF1 | c.21942G>C p.G7314= (on ENST00000372915; = p.G5359= on NM_012090.5) | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV57133872; called by muse, mutect2, varscan2
- MME | c.1479G>A p.L493= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV64709155; called by muse, mutect2, varscan2
- MST1 | c.1375C>T p.L459= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs1418762455, COSV99610805; called by muse, mutect2, varscan2
- MTBP | c.2709G>A p.K903= | Silent (SNP) | VAF 43/132 reads (33%) | catalogued as rs1183898958, COSV59964920; called by muse, mutect2, varscan2
- MYO3A | c.2310G>A p.E770= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as rs1228066124, COSV56341207, COSV99778790; called by muse, mutect2, varscan2
- NBEAL2 | c.7734C>T p.I2578= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV99436105, COSV99436983; called by muse, mutect2
- NF1 | c.3759C>T p.L1253= | Silent (SNP) | VAF 52/250 reads (21%) | catalogued as CD000082, COSV62212641; called by muse, mutect2, varscan2
- NR1I2 | c.1194C>T p.T398= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs769978712, COSV51769965; called by muse, mutect2, varscan2
- NUDT13 | c.927G>A p.L309= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs1388772859, COSV61969551; called by muse, mutect2, varscan2
- OAS2 | c.537C>T p.V179= | Silent (SNP) | VAF 40/72 reads (56%) | catalogued as COSV60803647; called by muse, mutect2, varscan2
- OR8H2 | c.621G>A p.L207= | Silent (SNP) | VAF 30/121 reads (25%) | catalogued as COSV57946577; called by muse, mutect2, varscan2
- PAX1 | c.393C>T p.I131= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs1422114692, COSV68272738; called by muse, mutect2, varscan2
- PER2 | c.2811C>G p.L937= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV54526022; called by muse, mutect2, varscan2
- PGLYRP4 | c.168C>G p.V56= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV62835962; called by muse, mutect2, varscan2
- PPM1E | c.1827G>A p.E609= | Silent (SNP) | VAF 28/124 reads (23%) | catalogued as rs1011779488, COSV57571948; called by muse, mutect2, varscan2
- PPP6R1 | c.253C>T p.L85= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV69800300; called by muse, mutect2, varscan2
- PRR5 | c.804G>A p.A268= (on ENST00000336985 / NM_181333.4; = p.A259= on NM_015366.4) | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs372443410; called by muse, mutect2, varscan2
- PRRC2B | c.5526C>G p.L1842= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV100260812, COSV57645893; called by muse, mutect2, varscan2
- PRSS21 | c.822C>T p.I274= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV50051870; called by muse, mutect2, varscan2
- PSD | c.2193C>T p.V731= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV50052184; called by muse, mutect2, varscan2
- RNF213 | c.13704G>A p.V4568= | Silent (SNP) | VAF 52/199 reads (26%) | catalogued as rs569181011, COSV60404726; called by muse, mutect2, varscan2
- RNF44 | c.319C>T p.L107= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as rs1355824823, COSV99221914; called by muse, mutect2
- RXFP4 | c.657C>T p.V219= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV58146312; called by muse, mutect2, varscan2
- SDC1 | c.342C>T p.L114= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV54340921; called by muse, mutect2, varscan2
- SERINC2 | c.1344C>G p.L448= (on ENST00000373709 / NM_178865.5; = p.L452= on NM_018565.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/116 reads (30%) | catalogued as COSV65491232; called by muse, mutect2, varscan2
- SH3GL1 | c.1062C>T p.F354= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV53658767; called by muse, mutect2, varscan2
- SH3GL1 | c.277C>T p.L93= | Silent (SNP) | VAF 45/114 reads (39%) | catalogued as COSV54175708; called by muse, mutect2, varscan2
- SIPA1 | c.886C>T p.L296= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV101255833; called by muse, mutect2
- SLC2A14 | c.1188C>G p.V396= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV61587754; called by muse, mutect2, varscan2
- SLC5A5 | c.942C>T p.L314= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV55834367; called by muse, mutect2, varscan2
- SNX17 | c.780G>C p.L260= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV52007742; called by muse, mutect2, varscan2
- SOSTDC1 | c.330C>G p.L110= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV61049231, COSV61049639; called by muse, mutect2, varscan2
- SOWAHA | c.525G>A p.E175= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs956204207, COSV66332614; called by muse, mutect2, varscan2
- SP3 | c.564C>T p.F188= | Silent (SNP) | VAF 70/207 reads (34%) | catalogued as COSV59465668, COSV59469605; called by muse, mutect2, varscan2
- SSTR1 | c.687C>G p.L229= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV57456976; called by muse, mutect2, varscan2
- STAG2 | c.2364C>T p.F788= | Silent (SNP) | VAF 39/60 reads (65%) | catalogued as COSV54363196; called by muse, mutect2, varscan2
- STAT5A | c.1233C>G p.T411= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV61807780; called by muse, mutect2, varscan2
- STK24 | c.1278C>G p.L426= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV100924978; called by muse, varscan2
- SYNE2 | c.10353G>A p.L3451= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV59961157; called by muse, mutect2, varscan2
- SZT2 | c.5502C>T p.L1834= (on ENST00000634258 / NM_001365999.1; = p.L1777= on NM_015284.4) | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV65172341; called by muse, mutect2, varscan2
- TAAR5 | c.247C>T p.L83= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs747512080, COSV57799551; called by muse, mutect2, varscan2
- TACC2 | c.4206C>T p.L1402= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as rs1168394869, COSV57765357; called by muse, mutect2, varscan2
- TACO1 | c.216G>A p.P72= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs755953211, COSV51976161; called by muse, varscan2
- TALDO1 | c.978G>A p.L326= | Silent (SNP) | VAF 11/17 reads (65%) | catalogued as COSV59798133; called by muse, mutect2, varscan2
- TCERG1 | c.2709C>T p.F903= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV57039985, COSV99695080; called by muse, mutect2, varscan2
- THOC2 | c.912G>A p.A304= | Silent (SNP) | VAF 57/86 reads (66%) | catalogued as rs770868310, COSV55551663; called by muse, mutect2, varscan2
- TMEM74B | c.273C>G p.V91= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV67892163; called by muse, mutect2, varscan2
- TNXB | c.351C>A p.L117= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as COSV64484495; called by muse, mutect2, varscan2
- TRPC5 | c.591G>A p.L197= | Silent (SNP) | VAF 47/64 reads (73%) | catalogued as COSV53298183, COSV99461745; called by muse, mutect2, varscan2
- TSC1 | c.99C>A p.L33= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV53770795; called by muse, mutect2, varscan2
- TTN | c.99394T>C p.L33132= (on ENST00000591111; = p.L25708= on NM_003319.4) | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as COSV60222439; called by muse, mutect2, varscan2
- UPF3B | c.852C>G p.L284= (on ENST00000276201 / NM_080632.3; = p.L271= on NM_023010.3) | Silent (SNP) | VAF 31/45 reads (69%) | catalogued as COSV52230886; called by muse, mutect2, varscan2
- VCPIP1 | c.2757G>A p.Q919= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV60049284; called by muse, varscan2
- WAC | c.720C>T p.H240= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as rs183083510, COSV61568696; called by muse, mutect2, varscan2
- XRN1 | c.2446C>T p.L816= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as COSV53815603; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504854 G>C | 5'Flank (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505009 G>A | 5'Flank (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- BEND6 | chr6:56954525 G>C | 5'Flank (SNP) | VAF 4/29 reads (14%) | catalogued as rs753742061; called by muse, mutect2
- CPLANE1 | c.*4834G>A | 3'UTR (SNP) | VAF 31/85 reads (36%) | catalogued as rs1450956266, COSV57068354; called by muse, mutect2, varscan2
- FMN1 | c.2044-2456C>G | Intron (SNP) | VAF 23/48 reads (48%) | catalogued as COSV57918496, COSV57928973; called by muse, mutect2, varscan2
- LDLRAD4 | c.182-8380G>A | Intron (SNP) | VAF 12/38 reads (32%) | catalogued as rs936834081, COSV63339583; called by muse, mutect2, varscan2
- NDUFV3 | c.170-5307G>C | Intron (SNP) | VAF 32/110 reads (29%) | catalogued as rs201154517, COSV61088199; called by muse, mutect2, varscan2
- PRKACB | c.47-34758C>T | Intron (SNP) | VAF 33/107 reads (31%) | catalogued as rs372658798; called by muse, mutect2, varscan2
- SSPOP | n.14854C>T | RNA (SNP) | VAF 4/14 reads (29%) | catalogued as rs1183986893, COSV100947468; called by muse, mutect2
- SYTL2 | c.1460-3074C>T | Intron (SNP) | VAF 16/115 reads (14%) | catalogued as COSV60361539; called by muse, mutect2, varscan2
- TTN | c.10360+4885C>G | Intron (SNP) | VAF 19/71 reads (27%) | catalogued as COSV60222477; called by muse, mutect2, varscan2
- ZNF521 | c.-50C>T | 5'UTR (SNP) | VAF 9/21 reads (43%) | catalogued as rs774317201, COSV100832374; called by muse, varscan2
